CCDI case PBBVNV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/eddfb94e-b3a3-4cf4-9aa6-56f6441c6502

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Choroid plexus papilloma, NOS: ICD-O-3 morphology code: 9390/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.7 years (609 days).

Biospecimens (3 samples)
- Sample 0DIDS4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DIDSC, 0DIDTV (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
